CCDI case PBBIBT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/686928c9-bcd8-4939-bf6c-d544c6b555cb

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.8 years (6,138 days).

Biospecimens (3 samples)
- Sample 0DA4HY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DA4I2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DA4I3: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
